Somatic mutation profile of tumor specimen TCGA-AG-3602-01A (aliquot TCGA-AG-3602-01A-02D-1989-10) from TCGA case TCGA-AG-3602, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 66.7 years (24,350 days).
Specimen TCGA-AG-3602-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a971a5a9-846a-4c67-878b-e0407b01bbcb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-3602-10A (Blood Derived Normal), aliquot TCGA-AG-3602-10A-01W-1990-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/690c41c9-e209-4b65-b8ae-d4346c0fbaec

The open-access MAF lists 13 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 10, Silent 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DCLK3 | c.1439C>T p.P480L | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369906307; called by muse, mutect2, varscan2
- ERN2 | c.2663G>A p.R888Q | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs377283392, COSV99891700; called by muse, mutect2, varscan2
- FBN3 | c.8180G>A p.R2727Q | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs75174438; called by muse, varscan2
- PCDHA7 | c.1367C>T p.A456V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.37); catalogued as COSV100971542; called by muse, mutect2
- PPP3CC | c.4T>C p.S2P | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as COSV99252194; called by muse, mutect2, varscan2
- SBK2 | c.7G>A p.G3S | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.073); catalogued as rs755066296, COSV100705153; called by muse, varscan2
- SURF6 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 43/79 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200287750, COSV100921179; called by muse, mutect2, varscan2
- TMEM192 | c.634dup p.I212Nfs*25 | Frame Shift Ins (INS) | VAF 150/499 reads (30%) | catalogued as rs780881872; called by mutect2, pindel, varscan2
- UPF1 | c.1609G>A p.A537T (on ENST00000599848 / NM_001297549.2; = p.A526T on NM_002911.4) | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV53199157; called by muse, mutect2, varscan2
- ZNF2 | c.1173T>G p.F391L (on ENST00000611147 / NM_001291605.2; = p.F378L on NM_021088.4) | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99728380, COSV99728528; called by muse, mutect2, varscan2
- CCDC18 | c.3047G>T p.R1016I (on ENST00000343253 / NM_001306076.1; = p.R1017I on NM_206886.4) | Missense Mutation (SNP) | VAF 12/284 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DSPP | c.2196C>T p.S732= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as rs945729707; called by muse, mutect2, varscan2
- RAB40A | c.552G>A p.G184= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV100420950; called by muse, mutect2
